TCGA case TCGA-BA-A6DF — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b41fab9f-af83-4ea2-89fb-a5999b168412

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 80 years; Vital status: Dead; Days to death: 238 days.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C04.9; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 80.2 years (29,283 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N2b; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 28; Lymphatic invasion present: No; Margin status: Indeterminate; Perineural invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 44 days; Days to treatment end: 92 days; Treatment dose: 6,400 cGy; Treatment outcome: Complete Response; Number of fractions: 32; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 238 days; Disease response: Tumor Free.

Molecular and laboratory tests
- CDKN2A: Positive.
- Involved Tissue, NOS human papillomavirus (ISH): Negative.

Exposures
- Exposure type: Tobacco.
- Alcohol history: No; Alcohol drinks per day: 0; Alcohol days per week: 0.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BA-A6DF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 210 mg.
  Slide TCGA-BA-A6DF-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BA-A6DF-01A-02-TS2: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BA-A6DF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BA-A6DF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Close; Lymphovascular invasion: No; Alcohol history documented: Yes; Alcohol consumption frequency: 0; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 238 days; disease-specific survival: no event (censored), 238 days; progression-free interval: no event (censored), 238 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BA-A6DF-01A-11D-A30D-01): tumor purity 0.35, ploidy 2.03, whole-genome doublings 0.
